Surgical pathology report (de-identified scan), TCGA case TCGA-UF-A7JO, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-UF-A7JO-01A (Primary Tumor).

ICD-0-3
Carcinoma, squamous cell NOS
8070/3
Site Floor of mouth
C04.9
9/24/13

Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Floor of mouth

1 - "Lymph Nodes - Level 3 - Left":

- Thirteen lymph nodes uninvolved by metastatic carcinoma (0/13).

2 - "Lymph Nodes - Level 2 - Left":

- Seven lymph nodes uninvolved by metastatic carcinoma (0/7).

3 - "Lymph Nodes - Level 1 - Left":

- Seven lymph nodes uninvolved by metastatic carcinoma (0/7).

4 - "Lymph Nodes - Level 2 - Right":

- Four of ten lymph nodes involved by metastatic carcinoma (4/10), with capsular involvement.

5 - "Floor of mouth tumor + left jaw":

- Invasive squamous cell carcinoma, grade 2:

- Ulceration: present.

- Tumor size 4.5 cm.

- Soft tissue infiltration until muscular layer.

- Osseous tissue involved by neoplasia.

- Lymphatic invasion: not identified.

- Vascular invasion: not identified.

- Perineural invasion: not identified.

- Posterior margin of the jaw involved by squamous cell carcinoma.

- Other surgical margins uninvolved by carcinoma.

Source: NCI Genomic Data Commons file 1fe0aea4-37f3-43eb-b5cf-0c24afcc4c40 (TCGA-UF-A7JO.2B6217E6-EE67-460F-8191-CE4481D39D59.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).